Surgical pathology report (de-identified scan), TCGA case TCGA-97-A4M0, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-A4M0-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. RIGHT UPPER LOBE
2. LEVEL 4 LYMPH NODE, RIGHT
3. LEVEL 10 LYMPH NODE, RIGHT
4. LEVEL 7 LYMPH NODE, RIGHT
5. LEVEL 11 LYMPH NODE, RIGHT
- SEE ADDENDUM

1CD-0-3
adenocarcinoma, with mixed subtypes
8255/3
site: lung, upper lobe c34.1
dw
10/4/12

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE: LOBECTOMY

- ADENOCARCINOMA, ACINAR PREDOMINANT (2.2 CM), WITH VISCERAL PLEURAL INVASION CONFIRMED BY AN ELASTIN STAIN (SEE NOTE).
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

Note: The tumor consists of acinar (40%), papillary (30%), micropapillary (20%) and lepidic (10%) components and measures 2.2 cm in greatest dimension microscopically. Results of mutational studies will be reported in addenda.

2. LYMPH NODE, RIGHT LEVEL 4: BIOPSY

- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

3. LYMPH NODE, RIGHT LEVEL 10: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

4. LYMPH NODE, RIGHT LEVEL 7: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

[page 2 of 8]
5. LYMPH NODE, RIGHT LEVEL 11: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

Specimens: 1: RIGHT UPPER LOBE
2: LEVEL 4 LYMPH NODE, RIGHT
3: LEVEL 10 LYMPH NODE, RIGHT
4: LEVEL 7 LYMPH NODE, RIGHT
5: LEVEL 11 LYMPH NODE, RIGHT

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

right upper

Procedure: Lobectomy

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

2.2cm

Visceral Pleura Invasion: Present

MARGINS

Bronchial Margin

**Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma**

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

**pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest
dimension surrounded by lung or visceral pleura without
bronchoscopic evidence of invasion more proximal than the lobar
bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less
in greatest dimension with any of the following features of extent:
involves main bronchus, 2 cm or more distal to the carina; invades
the visceral pleura; associated with atelectasis or obstructive
pneumonitis that extends to the hilar region but does not involve the
entire lung**

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number Examined

[page 3 of 8]
8

Number Involved

0

Distant Metastases (pM): Not applicable

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

F ex-smoker (35 pack-years) with a 1.3 cm RUL adenocarcinoma.

MACROSCOPIC DESCRIPTION:

The specimen is received in saline in five parts, each labeled with the patient's name.

1. Part one is labeled 'right upper lobe '. It consists of a right upper lobe of the lung measuring 16 x 10 x 3.5 cm. The bronchial margin measures 1.1 cm and vascular margin measures 1 cm at the hilum. The staple line measures 12 cm in length which is shaved and the parenchyma around it is inked blue. The pleura is grey-pink, glistening and received with a pre cut area at the lower aspect of the lung. At the pre cut area there is a grey-tan firm nodular area measuring 1.2 x 1 cm, located 3.2 cm from the hilum and 3.8 cm from the stapled line margin. The remainder of the parenchyma is pink-red, blotchy and crepitant. No other nodule grossly identified. Representative sections are submitted.
2. Part two is labeled ' level 4 lymph node right'. It consists of three anthracotic lymph nodes measuring from 0.3 cm up to 1.3 cm in largest dimension. Entirely submitted in one cassette.
3. Part three is labeled 'level 10 lymph node right '. It consists of one anthracotic lymph node measuring 1 x 1 x 0.5 cm. Entirely submitted in one cassette.
4. Part four is labeled 'level 7 lymph node right '. It consists of one anthracotic lymph node measuring 0.6 x 0.6 x 0.3 cm. Entirely submitted in one cassette.
5. Part five is labeled 'level 11 lymph node right '. It consists of one anthracotic lymph node measuring 1 x 0.8 x 0.5 cm. Entirely submitted in one cassette.

[page 4 of 8]
SUMMARY OF SECTIONS:

1A bronchial margin, shaved
1B vascular margin, shaved
1C-1F nodular area
1G stapled line margin
1H two lymph nodes from the hilum
2A entirely submitted
3A entirely submitted
4A entirely submitted
5A entirely submitted

SPECIAL PROCEDURES:

Final Diagnosis performed by

- - -

ADDENDUM #1:

INTEGRATED ONCOLOGY

**MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS**

Referring Physician:
Body Site: Lung
Specimen Type: Slides
Clinical Data: Adenocarcinoma

RESULTS: Positive for a p.G12C (c.34G>T) mutation in codon 12 of the KRAS gene.

INTERPRETATION:
Mutations in the KRAS gene are reported to correlate with poor prognosis and resistance to tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer.

COMMENT:
KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC)

[page 5 of 8]
patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATIONS:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer, 2005; 92:11-139

Pao W, Wang TY, et al. PLoS Medicine, 2005; 2(1):57-61

Eberhard DA, Johnson BE, et al. J Clin Oncol, 2005; 23:5900-5909

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8):2538-2544

CRC

DiFiore C, Blanchard F, et al. Br J Cancer, 20007; 96:1166-1169

Lievre A, Bachet J-B, et al. Cancer Res, 2006; 66:3992-3995,

The test was developed and its performance characteristics determined by The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

[page 6 of 8]
Electronically signed by:
Date:

Addendum #1 performed by

ADDENDUM #2:

INTEGRATED ONCOLOGY

EGFR Mutation Analysis

Referring Physician:

Body Site: Lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

[page 7 of 8]
COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 80% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

1. Azzoli CG, et al. J. Clin Oncol. 2009; 27:6251-6266.
2. Jackman DM, et al. Clin Carcinoma Res. 2009; 15:5267-5273.
3. Mok TS, et al. N Engl J Med. 2009; 361:947-957.
4. Sharma SV, et al. Nat Rev Carcinoma. 2007; 7:169-181.

DISCLAIMER:

[page 8 of 8]
The test was developed and its performance characteristics determined by the laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Electronically signed by:
Date:

Addendum #2 performed by

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.
The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.
The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 05a9614c-4206-45e7-acff-5be61b6acd5c (TCGA-97-A4M0.0ACA9251-2F21-49E1-9E56-4D7359EF614F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).